Somatic mutation profile of tumor specimen 0E1CWY from CCDI case PBCVYS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1CWY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 119e1294-d2c9-4fb4-a974-a70b4621707b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1CX5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66eaf6c5-641d-437b-ae19-3b1f5c3f4749

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, 3'UTR 3, Intron 2, Nonsense Mutation 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF462 | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 157/179 reads (88%) | catalogued as rs562767308, COSV52942682; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL20A1 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 154/310 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100489995; called by muse, mutect2, varscan2
- DDX3X | c.1036G>T p.D346Y (on ENST00000399959; = p.D347Y on NM_001356.5) | Missense Mutation (SNP) | VAF 175/433 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863429; called by muse, mutect2, varscan2
- DNAH2 | c.5345C>T p.T1782M | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145112814; called by muse, mutect2, varscan2
- FCGBP | c.10195C>T p.R3399C | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs146863017; called by muse, mutect2, varscan2
- HINFP | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 103/273 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs773121194; called by muse, mutect2, varscan2
- MROH9 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 158/432 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs765634568, COSV63012369; called by muse, mutect2
- MSR1 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 234/567 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs766405850, COSV100027928, COSV50542362; called by muse, mutect2, varscan2
- PTCH1 | c.2908G>T p.E970* | Nonsense Mutation (SNP) | VAF 76/547 reads (14%) | catalogued as CM045082, COSV59496165; called by muse, mutect2, varscan2
- PTCH1 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 190/360 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59480383; called by muse, mutect2, varscan2
- TPTE | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 143/686 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.017); catalogued as rs753249051; called by muse, mutect2, varscan2
- ZNF274 | c.478G>A p.A160T (on ENST00000610905; = p.A55T on NM_016324.3) | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs781621896; called by muse, mutect2, varscan2
- CYP2F1 | c.1117A>G p.R373G | Missense Mutation (SNP) | VAF 115/210 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- LRRC66 | c.1688_1689insGAA p.H563delinsQN | In Frame Ins (INS) | VAF 104/230 reads (45%) | called by mutect2, varscan2
- PCLO | c.10391C>A p.T3464N | Missense Mutation (SNP) | VAF 200/489 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PTCH1 | c.1901dup p.H634Qfs*20 | Frame Shift Ins (INS) | VAF 172/193 reads (89%) | called by mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 48/630 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- DTNB | c.222C>T p.T74= | Silent (SNP) | VAF 41/568 reads (7%) | catalogued as rs575706107; called by muse, mutect2
- GP6 | c.585C>T p.S195= | Silent (SNP) | VAF 60/152 reads (39%) | catalogued as rs768628583; called by muse, varscan2
- ISM1 | c.1050C>T p.D350= | Silent (SNP) | VAF 77/161 reads (48%) | catalogued as rs572363345, COSV52603697; called by muse, mutect2, varscan2
- RPTN | c.288C>A p.G96= | Silent (SNP) | VAF 26/354 reads (7%) | called by muse, mutect2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 48/624 reads (8%) | catalogued as rs1267156464; called by muse, mutect2
- ADGRG6 | c.*216T>A | 3'UTR (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- ATXN7 | c.2661+1184C>T | Intron (SNP) | VAF 22/671 reads (3%) | called by muse, mutect2
- CRACR2B | c.953+35G>C | Intron (SNP) | VAF 79/201 reads (39%) | catalogued as rs777542668; called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 46/454 reads (10%) | called by muse, varscan2
- SELENOI | c.*14G>T | 3'UTR (SNP) | VAF 42/568 reads (7%) | called by muse, mutect2
